Somatic mutation profile of tumor specimen TCGA-A2-A0CX-01A (aliquot TCGA-A2-A0CX-01A-21W-A019-09) from TCGA case TCGA-A2-A0CX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.4 years (19,152 days).
Specimen TCGA-A2-A0CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 140f3d45-919d-47d1-a9e5-57e4473b86f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0CX-10A (Blood Derived Normal), aliquot TCGA-A2-A0CX-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/134ba9da-b50c-4ff7-9404-4f0d0b920d04

The open-access MAF lists 290 somatic variants for this specimen: 218 protein-altering or splice-affecting, 63 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 63, Nonsense Mutation 20, Splice Region 4, Intron 4, RNA 3, 3'Flank 1, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as rs199473121, CM097640, COSV61132438; ClinVar: pathogenic / uncertain significance / not provided; called by muse, mutect2
- ABLIM3 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as rs764090826, COSV58639412; called by muse, mutect2, varscan2
- AC008397.2 | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53204706, COSV53209646; called by muse, mutect2, varscan2
- ACAD11 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53893650; called by muse, mutect2, varscan2
- ACO2 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53439510; called by muse, mutect2, varscan2
- ACSM2A | c.1390G>A p.D464N (on ENST00000219054; = p.D385N on NM_001308169.2) | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99525796; called by muse, mutect2
- ADCY8 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.037); catalogued as COSV99036578; called by muse, mutect2, varscan2
- AGPS | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV51561171; called by muse, mutect2, varscan2
- AHCTF1 | c.1405G>C p.E469Q (on ENST00000366508; = p.E443Q on NM_015446.5) | Missense Mutation (SNP) | VAF 31/861 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV58252000; called by muse, mutect2
- AL645922.1 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100191554; called by muse, mutect2
- ALDH1L2 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51553051; called by muse, mutect2, varscan2
- AMBN | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV59825108, COSV59825190, COSV59825299; called by muse, mutect2, varscan2
- ANKRD28 | c.2600G>A p.G867E | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101080982; called by muse, mutect2
- ANKRD34B | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); catalogued as COSV58613372, COSV58613969; called by muse, mutect2, varscan2
- APPL1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV55699746; called by muse, mutect2, varscan2
- ARHGAP5 | c.4189C>T p.Q1397* (on ENST00000345122 / NM_001030055.2; = p.Q1396* on NM_001173.3) | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | catalogued as COSV53734968; called by muse, mutect2, varscan2
- ARSF | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100839554, COSV63839052; called by muse, mutect2
- ASIC3 | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52502299; called by muse, mutect2, varscan2
- ATP2B1 | c.1486C>A p.H496N | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV99666272; called by muse, mutect2, varscan2
- BAZ1B | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs782432522, COSV59991208; called by muse, mutect2
- BCL2L1 | c.72G>C p.W24C | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.18); catalogued as COSV100304865; called by muse, mutect2
- BICD1 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.468); catalogued as COSV55674896; called by muse, mutect2, varscan2
- BID | c.710G>A p.R237K (on ENST00000317361 / NM_197966.2; = p.R191K on NM_001196.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV58006095; called by muse, mutect2, varscan2
- BLOC1S2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs999416610, COSV58394612; called by muse, varscan2
- BMT2 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV51774754, COSV51776523; called by muse, mutect2, varscan2
- BRIP1 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 100/358 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51994263, COSV52009007; called by muse, mutect2, varscan2
- BRPF3 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60206025; called by muse, mutect2, varscan2
- BTD | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.268); catalogued as COSV57728470; called by muse, mutect2, varscan2
- BTK | c.684G>C p.M228I | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV58117474; called by muse, mutect2, varscan2
- C11orf87 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.96); catalogued as COSV59356105; called by muse, mutect2, varscan2
- CABCOCO1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.159); catalogued as COSV57591773; called by muse, mutect2, varscan2
- CABS1 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV56732955, COSV56733085; called by muse, mutect2, varscan2
- CABYR | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 28/149 reads (19%) | catalogued as COSV59110198; called by muse, mutect2, varscan2
- CACNB2 | c.1079G>T p.R360M (on ENST00000324631 / NM_201596.3; = p.R305M on NM_000724.4) | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56644063; called by muse, mutect2
- CACNG6 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV53165691, COSV53167289; called by muse, mutect2, varscan2
- CALCOCO1 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 41/287 reads (14%) | catalogued as COSV50411777; called by muse, mutect2, varscan2
- CALCOCO1 | c.1224G>C p.W408C | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100017523; called by muse, mutect2
- CBFA2T2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60073080; called by muse, mutect2, varscan2
- CC2D1B | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99430377; called by muse, mutect2
- CCDC102B | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs199750681; called by muse, mutect2, varscan2
- CDC42BPB | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV63473910; called by muse, mutect2, varscan2
- CDCA2 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV55339206; called by muse, mutect2, varscan2
- CDHR5 | c.1698G>C p.Q566H (on ENST00000358353 / NM_001171968.2; = p.Q572H on NM_021924.5) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV100363867; called by muse, varscan2
- CDKL4 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV66508387, COSV66510524; called by muse, mutect2, varscan2
- CEP250 | c.3691C>A p.P1231T | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV61168280; called by muse, mutect2, varscan2
- CFAP44 | c.2246C>A p.S749Y | Missense Mutation (SNP) | VAF 173/614 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV55608654, COSV55613523; called by muse, mutect2, varscan2
- CHST9 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 33/467 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99411100; called by muse, mutect2
- CIC | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99360402; called by mutect2, varscan2
- CNN1 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV52955284; called by muse, mutect2, varscan2
- CS | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1334328712, COSV57523927; called by muse, mutect2, varscan2
- CSF1 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV60031997; called by muse, mutect2, varscan2
- CUL3 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 8/232 reads (3%) | catalogued as COSV100024936; called by muse, mutect2
- DCP1A | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs782339040, COSV53687132; called by muse, mutect2, varscan2
- DCTN4 | c.537G>A p.S179= | Splice Region (SNP) | VAF 29/110 reads (26%) | catalogued as rs757861882, COSV69781746; called by muse, mutect2, varscan2
- DDX41 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57902033; called by muse, mutect2, varscan2
- DDX5 | c.808A>C p.R270= | Splice Region (SNP) | VAF 43/328 reads (13%) | catalogued as COSV56747921; called by muse, mutect2, varscan2
- DEGS1 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV60378566; called by muse, mutect2, varscan2
- DENND4A | c.4480G>C p.E1494Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71265203; called by muse, mutect2, varscan2
- DEPDC4 | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV54553095; called by muse, mutect2, varscan2
- DHTKD1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV53801749; called by muse, varscan2
- DHX57 | c.1022C>G p.S341C | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54882351, COSV99770019; called by muse, mutect2
- DLG1 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 63/263 reads (24%) | catalogued as COSV58378032; called by muse, mutect2, varscan2
- DNAH17 | c.8755G>A p.E2919K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs750434977, COSV101101263; called by muse, mutect2
- DNAJB7 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV53423723, COSV99344481; called by muse, mutect2
- DNAJC10 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs371494397; called by muse, mutect2
- DNM2 | c.1903G>A p.E635K (on ENST00000355667 / NM_001005360.3; = p.E631K on NM_004945.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs761198315, COSV58957247; ClinVar: uncertain significance; called by muse, varscan2
- DOLK | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58279851; called by muse, mutect2, varscan2
- EFCAB7 | c.1401G>C p.L467F | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64313950; called by muse, mutect2, varscan2
- EFHC2 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69552765; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1620C>G p.I540M | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.904); catalogued as COSV51614352; called by muse, varscan2
- EPM2AIP1 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as COSV99212828; called by muse, varscan2
- ERCC1 | c.533C>G p.P178R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99185417; called by muse, mutect2
- ETV6 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV67148219; called by muse, mutect2, varscan2
- EVC | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.26); catalogued as COSV53829314; called by muse, mutect2
- EWSR1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 17/115 reads (15%) | catalogued as COSV58421598, COSV58426314; called by muse, mutect2, varscan2
- FAM171B | c.2264C>G p.P755R | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59000766; called by muse, mutect2, varscan2
- FAM83A | c.425T>A p.V142D | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52683913; called by muse, mutect2, varscan2
- FAM91A1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 82/820 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100593848; called by muse, mutect2, varscan2
- FASTKD3 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 65/254 reads (26%) | catalogued as COSV52941745; called by muse, mutect2, varscan2
- FAT1 | c.7117G>A p.D2373N | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV101499674; called by muse, mutect2
- FGD4 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as COSV56780501; called by muse, mutect2, varscan2
- FNBP4 | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55446369; called by muse, mutect2, varscan2
- FXR1 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.043); catalogued as COSV59761042; called by muse, mutect2, varscan2
- GAB3 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as COSV65818809; called by muse, mutect2, varscan2
- GCKR | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.041); catalogued as rs779171513, COSV53106535; called by muse, mutect2, varscan2
- GEMIN8 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs1301312201, COSV100257166; called by muse, mutect2, varscan2
- GSAP | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 35/244 reads (14%) | catalogued as rs757431131, COSV57528356; called by muse, mutect2, varscan2
- H1-3 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1253482218, COSV55096844, COSV99768672; called by muse, mutect2, varscan2
- HAO1 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV66491067, COSV66493652; called by muse, mutect2, varscan2
- HEG1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 140/893 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV60759387; called by muse, mutect2, varscan2
- HEPACAM | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV53428724; called by muse, mutect2, varscan2
- HMCN1 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99637004; called by muse, mutect2
- HMCN1 | c.6917G>A p.R2306Q | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.653); catalogued as rs137853916, COSV54894302; ClinVar: not provided; called by muse, mutect2
- HOOK3 | c.1547G>A p.R516K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100296148; called by muse, mutect2, varscan2
- HSPA9 | c.143C>G p.S48* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV51863259; called by muse, mutect2, varscan2
- HYDIN | c.12299G>A p.R4100K | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.194); catalogued as COSV66637239, COSV99061391; called by muse, mutect2, varscan2
- IFI16 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.604); catalogued as COSV99858284; called by muse, mutect2
- IL1RAP | c.635G>C p.C212S | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50759035, COSV50760384; called by muse, mutect2, varscan2
- IMPG2 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 69/594 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV51973663; called by muse, mutect2, varscan2
- INSRR | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63870936; called by muse, mutect2, varscan2
- INSYN2A | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV54730143; called by muse, mutect2, varscan2
- INTS10 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV101208755; called by muse, mutect2, varscan2
- ITGA1 | c.2075G>A p.G692E | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.828); catalogued as COSV50876532; called by muse, mutect2, varscan2
- ITPRID2 | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57469557; called by muse, mutect2, varscan2
- KCNH8 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 54/473 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60456823; called by muse, mutect2, varscan2
- KCNH8 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 28/617 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100111162, COSV60455785; called by muse, mutect2
- KDM5C | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV64762826; called by muse, mutect2, varscan2
- KIAA1841 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54372632; called by muse, mutect2, varscan2
- KIF14 | c.3016C>T p.H1006Y | Missense Mutation (SNP) | VAF 31/468 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as rs949610496, COSV100951107; called by muse, mutect2
- KL | c.2882G>C p.R961T | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV66307862; called by muse, mutect2, varscan2
- KLRK1 | c.457C>G p.H153D | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53699570, COSV99555295; called by muse, mutect2
- KPTN | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV99645937; called by muse, mutect2
- KPTN | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54548867, COSV99645938; called by muse, mutect2
- KRT34 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 14/194 reads (7%) | catalogued as COSV101222737; called by muse, mutect2
- LEPR | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV100756825; called by muse, mutect2
- LETM1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1039314263, COSV57098793; called by muse, mutect2
- LRP2 | c.6733G>C p.D2245H | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99790571; called by muse, mutect2
- LYSMD1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as rs766292534, COSV99766249; called by muse, mutect2
- MAP10 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs558263978, COSV69362761; called by muse, mutect2, varscan2
- MAP3K10 | c.839T>A p.F280Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV53420498; called by muse, mutect2, varscan2
- MBTD1 | c.867G>C p.M289I | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV64502800; called by muse, mutect2, varscan2
- MDC1 | c.1994G>A p.G665E | Missense Mutation (SNP) | VAF 153/283 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV64523292; called by muse, mutect2, varscan2
- MEIS1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55483591; called by muse, mutect2, varscan2
- METTL5 | c.525G>C p.K175N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV53625924; called by muse, mutect2, varscan2
- MKS1 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV100439845; called by muse, mutect2, varscan2
- MRPL53 | c.90G>A p.T30= | Splice Region (SNP) | VAF 6/80 reads (8%) | catalogued as COSV50688630, COSV99252249; called by muse, mutect2
- MRTFB | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV57956242, COSV57960796; called by muse, mutect2, varscan2
- MSH6 | c.3146C>T p.S1049F | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs1395294066, COSV52274566; called by muse, mutect2, varscan2
- MTO1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV64773131; called by muse, mutect2, varscan2
- MUC4 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as COSV100642468; called by muse, mutect2
- MUSK | c.1716G>T p.R572S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51895285, COSV99505262; called by muse, mutect2
- NAIF1 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as COSV66089843; called by muse, mutect2, varscan2
- NCOA6 | c.4115G>C p.R1372T | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV62861381; called by muse, mutect2, varscan2
- NEDD9 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV101053445; called by muse, mutect2
- NEK10 | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 39/373 reads (10%) | catalogued as rs560857654, COSV55354578; called by muse, mutect2, varscan2
- NET1 | c.727G>A p.D243N (on ENST00000355029 / NM_001047160.3; = p.D189N on NM_005863.5) | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV61790809; called by muse, mutect2, varscan2
- NFKBIZ | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV58199423; called by muse, mutect2, varscan2
- NLRP11 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV64085706; called by muse, mutect2, varscan2
- NLRP4 | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.7); catalogued as COSV56708042; called by muse, varscan2
- NLRP8 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.387); catalogued as rs1168646598, COSV52583485, COSV52594482; called by muse, varscan2
- NOMO1 | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as rs771995798, COSV55057048; called by muse, mutect2, varscan2
- NOX3 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV99343718; called by muse, mutect2
- NSUN3 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 15/126 reads (12%) | catalogued as COSV58933939; called by muse, mutect2, varscan2
- NVL | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs755757900, COSV55870289; called by muse, mutect2, varscan2
- OCIAD1 | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV51900082; called by muse, mutect2, varscan2
- OR3A1 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV100041858; called by muse, mutect2
- PAK1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.434); catalogued as COSV53693558; called by muse, mutect2, varscan2
- PANK2 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM060411, COSV57253014; called by muse, mutect2, varscan2
- PER1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57917343; called by muse, mutect2, varscan2
- PGAM4 | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV100431845; called by muse, mutect2
- PKD2L2 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV51794774, COSV51800162; called by muse, mutect2, varscan2
- PKP2 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs368986542, CM152697, COSV50728922; called by muse, mutect2, varscan2
- PNLIPRP3 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV65046959, COSV65047045; called by muse, mutect2, varscan2
- POLR1G | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV50003663; called by muse, mutect2, varscan2
- PPIG | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV99645034; called by muse, mutect2
- PRDM10 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100457081; called by muse, mutect2
- PRR5L | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV61120191; called by muse, mutect2, varscan2
- PSMA1 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV67165706; called by muse, mutect2, varscan2
- PWWP3B | c.1332G>C p.K444N | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100531106, COSV100531679; called by muse, mutect2
- R3HDM2 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs777846007, COSV60413426; called by muse, mutect2, varscan2
- RABEP1 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | catalogued as rs1475920767, COSV52582749; called by muse, mutect2, varscan2
- RASGRF1 | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.575); catalogued as COSV101174827; called by muse, mutect2
- RBPJL | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59212730; called by muse, mutect2, varscan2
- RGL3 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 32/191 reads (17%) | catalogued as rs1213961717, COSV62697200; called by muse, mutect2, varscan2
- RNF213 | c.15172G>T p.D5058Y | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100301645; called by muse, mutect2
- RRM1 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56162927; called by muse, mutect2, varscan2
- RSPH10B | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs140401316; called by muse, mutect2
- RSPH10B2 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1347171319, COSV51867671; called by mutect2, varscan2
- SAMD9 | c.2834G>A p.G945E | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV66073030; called by muse, mutect2, varscan2
- SART3 | c.2268C>G p.I756M (on ENST00000228284; = p.I738M on NM_014706.4) | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV57205422; called by muse, mutect2, varscan2
- SCAPER | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1447903246, COSV100239794, COSV57733332; called by muse, mutect2
- SEC24D | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54876881, COSV54884346; called by muse, mutect2, varscan2
- SENP2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | catalogued as COSV99957746; called by muse, mutect2
- SH3TC2 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60460837; called by muse, mutect2, varscan2
- SLC13A3 | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs752308476, COSV51711900; called by muse, mutect2, varscan2
- SLC25A25 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1186536546, COSV100895422; called by muse, mutect2
- SLMAP | c.2050G>C p.E684Q (on ENST00000428312 / NM_001377924.1; = p.E746Q on NM_007159.5) | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV99909336; called by muse, mutect2
- SMG8 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as COSV56284039; called by muse, mutect2, varscan2
- SNRNP200 | c.3157G>C p.E1053Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV100107789, COSV100108140; called by muse, mutect2
- SNRNP200 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100108142; called by muse, mutect2
- SP100 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99894440; called by muse, mutect2
- SPEF2 | c.1590C>G p.C530W | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV100609111; called by muse, mutect2
- SPHKAP | c.1937G>A p.R646K | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as COSV100764596, COSV60891788; called by muse, mutect2
- STAM | c.41-1G>C p.X14_splice | Splice Site (SNP) | VAF 58/330 reads (18%) | catalogued as COSV66324925; called by muse, mutect2, varscan2
- STXBP5L | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV56500435; called by muse, mutect2, varscan2
- SULF1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.32); catalogued as COSV99484528; called by muse, mutect2
- SYNE3 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV62077908; called by muse, mutect2, varscan2
- TCEAL2 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 61/370 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.165); catalogued as COSV61197149, COSV61197296; called by muse, mutect2, varscan2
- TLK2 | c.1219G>C p.E407Q (on ENST00000326270 / NM_001284333.2; = p.E385Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV58297385; called by muse, mutect2, varscan2
- TMEM19 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV99877204; called by muse, mutect2
- TMEM89 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV56570064; called by muse, mutect2, varscan2
- TOP2A | c.570C>G p.F190L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as COSV70732059; called by muse, mutect2, varscan2
- TPH1 | c.549A>C p.K183N | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV100001127; called by muse, mutect2
- TPM2 | c.561G>A p.E187= | Splice Region (SNP) | VAF 17/90 reads (19%) | catalogued as COSV61404771; called by muse, mutect2, varscan2
- TRIM10 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 158/478 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV64993015; called by muse, varscan2
- TUBA1B | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.403); catalogued as COSV60136283; called by muse, mutect2, varscan2
- UBAP2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100671530, COSV100672031; called by muse, mutect2
- UFD1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319213313, COSV54243523; called by muse, mutect2, varscan2
- USP33 | c.1236C>G p.I412M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV62468299; called by muse, mutect2, varscan2
- VSTM1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV58073928; called by muse, mutect2, varscan2
- VWA8 | c.2446C>T p.L816F | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99863717, COSV99865387; called by muse, mutect2
- WBP11 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.441); catalogued as COSV99660939; called by muse, mutect2
- WDR43 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs752884679, COSV56097978; called by muse, mutect2, varscan2
- WDR44 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as COSV99562023; called by muse, mutect2
- WDR82 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV56601072; called by muse, mutect2, varscan2
- ZC3H7A | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV63268493; called by muse, mutect2, varscan2
- ZFHX3 | c.6103C>T p.Q2035* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV51708919; called by muse, mutect2, varscan2
- ZNF208 | c.3830G>C p.G1277A | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV68100661; called by muse, mutect2, varscan2
- ZNF23 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 16/181 reads (9%) | catalogued as COSV100612296; called by muse, mutect2
- ZNRF2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV59910381; called by muse, mutect2, varscan2
- ZRANB3 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV51494224, COSV51495887; called by muse, mutect2, varscan2
- ZSCAN10 | c.790G>A p.E264K (on ENST00000252463; = p.E319K on NM_032805.3) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV52970437; called by muse, mutect2
- ZXDB | c.2374G>C p.D792H | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs12845530, COSV66492333; called by muse, mutect2, varscan2
- ZZZ3 | c.2361G>C p.R787S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV100890370, COSV66231268; called by muse, mutect2, varscan2
- CCL23 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2
- CD300LF | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2
- DNAJB14 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2
- PPHLN1 | c.946del p.V316* | Frame Shift Del (DEL) | VAF 25/243 reads (10%) | called by mutect2, pindel, varscan2
- ABCC1 | c.2772C>T p.I924= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV60680486; called by muse, mutect2, varscan2
- ABCC12 | c.2517C>T p.V839= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs746329847, COSV60911626; called by mutect2, varscan2
- ADAR | c.1488G>T p.L496= | Silent (SNP) | VAF 27/358 reads (8%) | catalogued as COSV99426852; called by muse, mutect2
- ATP7B | c.1392G>A p.G464= | Silent (SNP) | VAF 41/203 reads (20%) | catalogued as rs1287996513, COSV54435262, COSV99666064; called by muse, mutect2, varscan2
- B4GAT1 | c.945C>T p.P315= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs758403661, COSV100240240, COSV60819612; called by muse, mutect2, varscan2
- BMPR2 | c.714G>A p.Q238= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV104424157, COSV65807585; called by muse, mutect2, varscan2
- BPGM | c.285G>A p.L95= | Silent (SNP) | VAF 41/221 reads (19%) | catalogued as COSV61323899; called by muse, mutect2, varscan2
- BRINP1 | c.1866G>C p.R622= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as COSV56292275; called by muse, mutect2, varscan2
- C12orf40 | c.36G>C p.L12= | Silent (SNP) | VAF 35/252 reads (14%) | catalogued as COSV61129482; called by muse, mutect2, varscan2
- C2CD3 | c.4179G>A p.L1393= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as rs761651691, COSV58089677; called by muse, mutect2, varscan2
- CACNB1 | c.408C>T p.I136= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV100703634; called by muse, mutect2
- CCDC88C | c.2184G>A p.R728= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV66234179; called by muse, mutect2, varscan2
- DDX42 | c.1161G>A p.L387= | Silent (SNP) | VAF 7/147 reads (5%) | catalogued as COSV100835111; called by muse, mutect2
- DTL | c.6C>G p.L2= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100877297; called by muse, mutect2
- EDDM3A | c.366C>T p.Y122= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as rs1566350112, COSV58794784; called by muse, mutect2, varscan2
- GALNT15 | c.63G>A p.L21= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as COSV60215353; called by muse, mutect2, varscan2
- IFNA17 | c.369G>T p.V123= | Silent (SNP) | VAF 101/662 reads (15%) | catalogued as COSV69738080; called by muse, mutect2, varscan2
- IL27RA | c.420C>T p.S140= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1568500384, COSV54598951; called by muse, mutect2, varscan2
- INTS8 | c.2172C>T p.I724= | Silent (SNP) | VAF 47/391 reads (12%) | catalogued as rs137943099; called by muse, mutect2, varscan2
- KLHL1 | c.1920C>T p.V640= | Silent (SNP) | VAF 31/313 reads (10%) | catalogued as rs372198907; called by muse, mutect2, varscan2
- LRRIQ4 | c.1053G>A p.L351= | Silent (SNP) | VAF 38/288 reads (13%) | catalogued as COSV61618656, COSV61619217; called by muse, mutect2, varscan2
- MAGEC3 | c.240C>T p.L80= | Silent (SNP) | VAF 46/347 reads (13%) | catalogued as rs144765729, COSV100026226; called by muse, mutect2, varscan2
- MAGED2 | c.1593C>T p.I531= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV54496933; called by muse, mutect2, varscan2
- MDN1 | c.4527G>A p.L1509= | Silent (SNP) | VAF 31/196 reads (16%) | catalogued as COSV65517310; called by muse, mutect2, varscan2
- MED12 | c.570C>T p.I190= | Silent (SNP) | VAF 31/193 reads (16%) | catalogued as COSV61332060; called by muse, mutect2, varscan2
- MED26 | c.1309C>T p.L437= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99659921, COSV99660237; called by muse, mutect2
- MEX3A | c.867G>A p.A289= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as rs1205788313, COSV101348973; called by muse, mutect2
- MYH7B | c.1503C>T p.I501= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs368976358; called by muse, mutect2, varscan2
- MYLK | c.3084C>T p.N1028= | Silent (SNP) | VAF 73/163 reads (45%) | catalogued as rs751399308, COSV60604998; called by muse, mutect2, varscan2
- NLRP4 | c.117C>G p.L39= | Silent (SNP) | VAF 66/324 reads (20%) | catalogued as COSV56708034; called by muse, varscan2
- NOB1 | c.138C>G p.L46= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV52060830; called by muse, mutect2, varscan2
- NUP188 | c.4821C>T p.F1607= | Silent (SNP) | VAF 52/395 reads (13%) | catalogued as rs755350781, COSV65330159; called by muse, mutect2, varscan2
- OGT | c.909C>G p.L303= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV101035661; called by muse, mutect2
- OR2L13 | c.375C>T p.I125= | Silent (SNP) | VAF 78/904 reads (9%) | catalogued as COSV63562027; called by muse, mutect2
- PA2G4 | c.414G>A p.R138= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV99918067; called by muse, mutect2
- PAQR3 | c.726G>A p.V242= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV55008495; called by muse, mutect2, varscan2
- PARD3 | c.3753G>A p.Q1251= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV61048581, COSV61061464; called by muse, mutect2, varscan2
- PBDC1 | c.480C>T p.I160= | Silent (SNP) | VAF 25/290 reads (9%) | catalogued as COSV100972884; called by muse, mutect2
- PCDHA10 | c.1359G>A p.A453= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs372428918, COSV56494213; called by mutect2, varscan2
- PCDHAC1 | c.319C>T p.L107= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV53837199; called by muse, mutect2, varscan2
- PCDHGA2 | c.705G>C p.A235= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV53900566, COSV53952335; called by muse, mutect2, varscan2
- PCDHGA2 | c.2139G>A p.A713= | Silent (SNP) | VAF 9/166 reads (5%) | catalogued as COSV53932471; called by muse, mutect2
- PRKAA1 | c.246C>T p.F82= | Silent (SNP) | VAF 24/450 reads (5%) | catalogued as rs775222791, COSV57182977, COSV99713460; called by muse, mutect2
- PRSS1 | c.324C>T p.I108= | Silent (SNP) | VAF 42/220 reads (19%) | catalogued as COSV61190522; called by muse, varscan2
- RTL3 | c.744C>A p.S248= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV58183161; called by muse, mutect2, varscan2
- SBF1 | c.4611C>T p.L1537= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs745827632, COSV62365795; called by muse, mutect2, varscan2
- SCMH1 | c.132C>T p.V44= | Silent (SNP) | VAF 151/393 reads (38%) | catalogued as rs1457015229, COSV58232451; called by muse, mutect2, varscan2
- SETD1A | c.69C>T p.I23= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as rs1388098314, COSV52685091; called by muse, mutect2, varscan2
- SGCE | c.1203G>A p.Q401= (on ENST00000647096; = p.Q365= on NM_003919.3) | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV99722989; called by muse, mutect2
- SLC10A2 | c.795G>A p.Q265= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV55357156; called by muse, mutect2, varscan2
- SLF2 | c.2859G>T p.L953= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV53270836; called by muse, mutect2, varscan2
- STAC2 | c.786C>T p.F262= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100336527; called by muse, mutect2
- SYNPO | c.1971G>A p.E657= (on ENST00000394243 / NM_001166208.2; = p.E413= on NM_007286.6) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs543447216; called by muse, mutect2
- TAS2R3 | c.513C>T p.F171= | Silent (SNP) | VAF 60/337 reads (18%) | catalogued as rs753226315, COSV56091625; called by muse, mutect2, varscan2
- TAZ | c.330C>T p.S110= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99186369; called by muse, mutect2
- TCTN3 | c.1431C>T p.L477= | Silent (SNP) | VAF 33/193 reads (17%) | catalogued as rs750185038, COSV56445458; called by muse, mutect2, varscan2
- TEKT5 | c.1437G>A p.P479= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs769738150, COSV51586689; called by muse, mutect2, varscan2
- TLCD5 | c.240C>G p.L80= (on ENST00000375095 / NM_001198671.2; = p.L102= on NM_174926.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/108 reads (5%) | catalogued as COSV100081202; called by muse, mutect2
- TTC7A | c.1485C>T p.L495= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs761530933, COSV55408502; called by muse, mutect2, varscan2
- UTP23 | c.732G>A p.Q244= | Silent (SNP) | VAF 101/503 reads (20%) | catalogued as COSV59123820, COSV59123923; called by muse, mutect2, varscan2
- VPS13B | c.2598C>T p.V866= | Silent (SNP) | VAF 12/281 reads (4%) | catalogued as COSV100663892; called by muse, mutect2
- WDR82 | c.684G>A p.V228= | Silent (SNP) | VAF 93/427 reads (22%) | catalogued as COSV56601083; called by muse, mutect2, varscan2
- ZNF23 | c.1035C>T p.F345= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as COSV61840475; called by muse, varscan2
- AL162726.3 | n.255+83275T>C | Intron (SNP) | VAF 99/623 reads (16%) | called by muse, mutect2, varscan2
- ATG16L1 | c.1204-1070G>A | Intron (SNP) | VAF 26/92 reads (28%) | catalogued as COSV61464300; called by muse, mutect2, varscan2
- C8orf31 | n.359G>A | RNA (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- DCHS2 | n.6109C>T | RNA (SNP) | VAF 19/196 reads (10%) | catalogued as COSV61769842; called by muse, mutect2
- DST | c.4297-1336G>A | Intron (SNP) | VAF 58/320 reads (18%) | catalogued as COSV54998262; called by muse, mutect2, varscan2
- MCF2 | chrX:139645586 G>A | 5'Flank (SNP) | VAF 18/108 reads (17%) | catalogued as COSV58478077; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100466 G>A | 3'Flank (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- TTN | c.34264+590G>A | Intron (SNP) | VAF 40/724 reads (6%) | catalogued as COSV100633644; called by muse, mutect2
- ZNF658B | n.2509C>G | RNA (SNP) | VAF 69/610 reads (11%) | called by muse, mutect2, varscan2
